Somatic mutation profile of tumor specimen TCGA-S9-A89Z-01A (aliquot TCGA-S9-A89Z-01A-11D-A36O-08) from TCGA case TCGA-S9-A89Z, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 40.7 years (14,858 days).
Specimen TCGA-S9-A89Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bef345ae-0676-4040-a5fe-5e3722834d1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A89Z-10A (Blood Derived Normal), aliquot TCGA-S9-A89Z-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/902a5bf1-9253-4905-8dd2-d2dd9535caf9

The open-access MAF lists 64 somatic variants for this specimen: 54 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 9, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNF4A | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs193922479, CM064051, COSV100290926, COSV57379860, COSV57386466; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACSM2B | c.246T>G p.N82K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV100313086; called by muse, mutect2, varscan2
- ADAM20 | c.1436A>G p.N479S | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.609); catalogued as rs915764798, COSV99833571; called by muse, mutect2, varscan2
- ADAMTS6 | c.3293T>G p.F1098C | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319729121, COSV100068589; called by muse, mutect2, varscan2
- CCDC110 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772802973, COSV56869806; called by muse, mutect2, varscan2
- CCDC174 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV100358697; called by muse, mutect2, varscan2
- CDH18 | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.058); catalogued as COSV99937921; called by muse, mutect2, varscan2
- CHEK1 | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.315); catalogued as COSV99629879; called by muse, mutect2, varscan2
- DCUN1D3 | c.440T>G p.F147C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100177063; called by muse, mutect2, varscan2
- DDX60 | c.4784A>G p.N1595S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.731); catalogued as COSV101190637; called by muse, mutect2, varscan2
- DHRS7C | c.301C>G p.L101V (on ENST00000330255 / NM_001220493.2; = p.L100V on NM_001105571.3) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV100364899; called by muse, mutect2, varscan2
- DNAH10 | c.2545A>G p.T849A (on ENST00000409039; = p.T788A on NM_207437.3) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV101292615; called by muse, mutect2, varscan2
- DNAH17 | c.5349G>A p.W1783* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV101103303; called by muse, mutect2, varscan2
- DNAH5 | c.10419+2T>A p.X3473_splice | Splice Site (SNP) | VAF 46/106 reads (43%) | catalogued as COSV99453620; called by muse, varscan2
- DSCAML1 | c.4057A>G p.I1353V (on ENST00000321322; = p.I1293V on NM_020693.4) | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.279); catalogued as COSV100357068; called by muse, mutect2
- DYNC1H1 | c.23G>C p.G8A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.76); PolyPhen probably damaging (0.981); catalogued as COSV100795338; called by muse, mutect2, varscan2
- EQTN | c.820A>G p.T274A | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV101192543; called by muse, mutect2, varscan2
- EYS | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs780733593; called by muse, mutect2
- FAT4 | c.13264T>C p.Y4422H | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV58678228; called by muse, mutect2, varscan2
- FLT3 | c.287A>G p.D96G | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99610055; called by muse, mutect2, varscan2
- FUCA2 | c.1258A>G p.T420A | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV99136198; called by muse, mutect2, varscan2
- GYS2 | c.1063-2A>G p.X355_splice | Splice Site (SNP) | VAF 41/100 reads (41%) | catalogued as rs1270543959, COSV99680204; called by muse, mutect2, varscan2
- HMCN1 | c.6346C>T p.L2116F | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV99634936; called by muse, mutect2, varscan2
- IL5 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as rs201066544; called by muse, mutect2, varscan2
- MORC1 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV99226650, COSV99227624; called by muse, mutect2, varscan2
- MTNR1B | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV99925322; called by muse, mutect2, varscan2
- MUC16 | c.3644G>T p.S1215I | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV101201391; called by muse, mutect2, varscan2
- MUC7 | c.1054G>T p.G352C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.437); catalogued as COSV100512375; called by muse, mutect2, varscan2
- NCAPG2 | c.2941T>C p.Y981H | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99317577; called by muse, mutect2
- NT5C2 | c.94T>A p.Y32N | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV100583718; called by muse, mutect2, varscan2
- NUP37 | c.335A>G p.Q112R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1038044682; called by muse, mutect2
- OPN4 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760979172, COSV54119845, COSV99618349; called by muse, mutect2, varscan2
- OPRM1 | c.711T>A p.C237* | Nonsense Mutation (SNP) | VAF 44/95 reads (46%) | catalogued as COSV100002330; called by muse, mutect2, varscan2
- OR10H2 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV100008874, COSV59945428; called by muse, mutect2
- OR12D2 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101011452; called by muse, mutect2, varscan2
- OR2G2 | c.400C>A p.H134N | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100189966; called by muse, mutect2, varscan2
- OR2G2 | c.689G>T p.R230M | Missense Mutation (SNP) | VAF 74/119 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV100189971, COSV60742382; called by muse, mutect2, varscan2
- OR4C15 | c.280A>G p.N94D (on ENST00000314644; = p.N40D on NM_001001920.2) | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100116063; called by muse, mutect2
- POLB | c.955A>G p.I319V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.044); catalogued as COSV99613416; called by muse, mutect2, varscan2
- PRRX2 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.619); catalogued as rs1430394400, COSV65241267; called by muse, mutect2, varscan2
- PTPRH | c.383A>G p.E128G | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.72); catalogued as COSV99671413; called by muse, mutect2, varscan2
- RAD51AP2 | c.2824T>A p.C942S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1418674246, COSV101208407; called by muse, mutect2, varscan2
- SHKBP1 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99199409; called by muse, mutect2, varscan2
- SPRR1B | c.112A>G p.K38E | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV100198398; called by muse, mutect2
- SYNDIG1L | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as COSV100526588; called by muse, mutect2, varscan2
- TERT | c.2572C>T p.R858W | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1322978833, COSV57248929; called by muse, mutect2
- TP53 | c.889del p.H297Tfs*48 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | catalogued as COSV53110176, COSV53729570; called by pindel, varscan2
- UBR5 | c.1684A>G p.M562V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs753988129, COSV99642202; called by muse, mutect2, varscan2
- UGT2A1 | c.1535T>A p.F512Y | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV99684854; called by muse, mutect2, varscan2
- USP34 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs1460725950, COSV101277193; called by muse, mutect2, varscan2
- ZNF354A | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100234644; called by muse, mutect2, varscan2
- PTH2R | c.1405_1408dup p.R470Hfs*19 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- VCX | c.98del p.K33Rfs*30 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel
- DSG4 | c.1899T>A p.I633= | Silent (SNP) | VAF 45/169 reads (27%) | catalogued as COSV100356375; called by muse, mutect2, varscan2
- EDA2R | c.33A>G p.Q11= | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as rs1449012194, COSV99490941; called by muse, mutect2, varscan2
- FAM217A | c.510T>C p.C170= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as COSV99212799; called by muse, mutect2, varscan2
- FGA | c.2088C>T p.F696= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs1024393205, COSV57392374; called by muse, mutect2, varscan2
- HMCN1 | c.3336T>C p.T1112= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as rs778305673, COSV99624480; called by muse, mutect2, varscan2
- HPN | c.1026C>T p.P342= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as rs953082804, COSV99385316; called by muse, mutect2, varscan2
- MAST4 | c.3876A>G p.S1292= (on ENST00000403625 / NM_001164664.2; = p.S1103= on NM_015183.3) | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV55127543; called by muse, mutect2, varscan2
- RC3H2 | c.564A>T p.G188= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100106911; called by muse, mutect2
- SDK1 | c.2868C>T p.D956= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as rs757713520, COSV67357395; called by muse, mutect2, varscan2
- DYRK3 | c.77+364C>T | Intron (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100895821; called by muse, mutect2, varscan2
